Somatic mutation profile of tumor specimen ALCH-B2V5-TTP1-A (aliquot ALCH-B2V5-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B2V5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.5 years (20,622 days).
Specimen ALCH-B2V5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 746109ce-4e40-44ff-94b1-e3dc001e4d48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2V5-NB1-A (Blood Derived Normal), aliquot ALCH-B2V5-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9a1be23-1e0b-42b8-9665-3bde76978c1c

The open-access MAF lists 84 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, Intron 8, Nonsense Mutation 6, Splice Site 3, 3'UTR 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 64/735 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs281875299, CM044563, COSV63021386; ClinVar: not provided / pathogenic; called by muse, mutect2
- AFP | c.443G>T p.C148F | Missense Mutation (SNP) | VAF 56/311 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778542569; called by muse, mutect2, varscan2
- ATF7IP2 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as COSV100202528; called by muse, mutect2, varscan2
- GABRE | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV64819024; called by muse, mutect2
- IGSF21 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 50/528 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV52124458; called by muse, mutect2
- IL1RL2 | c.991+1G>T p.X331_splice | Splice Site (SNP) | VAF 6/82 reads (7%) | catalogued as rs1475496972; called by muse, mutect2
- KIF2B | c.603C>A p.S201R | Missense Mutation (SNP) | VAF 99/545 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52137006; called by muse, mutect2, varscan2
- KRT6A | c.68C>G p.A23G | Missense Mutation (SNP) | VAF 126/1178 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs1423965394; called by muse, mutect2, varscan2
- MARCHF11 | c.567T>A p.D189E | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV60136456; called by muse, mutect2
- MYLK2 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.259); catalogued as COSV101044579, COSV101044658; called by muse, mutect2, varscan2
- MYOM2 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 63/385 reads (16%) | catalogued as COSV50735667, COSV50793656; called by muse, mutect2, varscan2
- PCDH15 | c.4572G>T p.M1524I (on ENST00000644397 / NM_001354429.2; = p.M1473I on NM_001142769.3) | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as COSV64707187; called by muse, mutect2
- PDE2A | c.2600C>A p.A867E | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV57807683; called by muse, mutect2
- SMCP | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 78/908 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1372610107; called by muse, mutect2
- SMOC1 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 47/582 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100734700; called by muse, mutect2
- SPEN | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.571); catalogued as rs771242557, COSV65357241, COSV65358454; called by muse, mutect2, varscan2
- TRIM72 | c.436C>A p.R146S | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs773457022; called by muse, mutect2, varscan2
- ANAPC2 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 33/367 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.026); called by muse, mutect2
- ANTXR2 | c.598A>T p.K200* | Nonsense Mutation (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- CLEC4F | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ERICH3 | c.4081G>T p.A1361S | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); called by muse, mutect2
- ERICH3 | c.4080G>T p.L1360F | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- FBXW2 | c.954G>T p.L318F | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HSPA12A | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- IDH3G | c.82-1G>T p.X28_splice | Splice Site (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- LAP3 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.098); called by muse, mutect2
- LRFN5 | c.31A>C p.I11L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, varscan2
- LUZP4 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.138); called by muse, varscan2
- LVRN | c.1484A>T p.Q495L | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED12 | c.4891A>T p.S1631C | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- METTL8 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 81/525 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYH1 | c.3803A>G p.E1268G | Missense Mutation (SNP) | VAF 88/925 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2
- NAV2 | c.2469G>T p.M823I (on ENST00000396087 / NM_001244963.2; = p.M800I on NM_145117.5) | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2
- NEURL2 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 31/310 reads (10%) | called by muse, mutect2, varscan2
- NOS2 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2
- NRXN1 | c.2473G>T p.V825L | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR52E6 | c.420C>A p.S140R | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPPA2 | c.3366-1G>T p.X1122_splice | Splice Site (SNP) | VAF 83/460 reads (18%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 46/748 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHKA2 | c.1375G>C p.G459R | Missense Mutation (SNP) | VAF 58/706 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PIEZO2 | c.4873G>T p.D1625Y | Missense Mutation (SNP) | VAF 38/558 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2
- PKP2 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PLD1 | c.2518C>T p.Q840* | Nonsense Mutation (SNP) | VAF 40/368 reads (11%) | called by muse, mutect2, varscan2
- PLP1 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.989); called by muse, mutect2
- PYROXD2 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2
- RAB34 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SATL1 | c.856C>A p.H286N (on ENST00000395409; = p.H473N on NM_001012980.2) | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SIGLEC6 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- SPTA1 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 46/548 reads (8%) | called by muse, mutect2
- TMEM177 | c.470A>C p.E157A | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TNFRSF1B | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- WDR35 | c.158G>T p.R53M | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ZNF430 | c.668A>T p.H223L | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- ZNF804B | c.1888T>G p.Y630D | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZSCAN32 | c.266C>T p.P89L (on ENST00000396846; = p.P90L on NM_001284527.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCST1 | c.681C>T p.A227= | Silent (SNP) | VAF 52/662 reads (8%) | catalogued as COSV55057497; called by muse, mutect2
- DRP2 | c.39C>A p.L13= | Silent (SNP) | VAF 80/620 reads (13%) | called by muse, mutect2, varscan2
- FAM171B | c.1977G>C p.L659= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV59009784; called by muse, mutect2
- LYAR | c.828G>T p.S276= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100603492; called by muse, mutect2, varscan2
- MAGEB1 | c.615G>T p.L205= | Silent (SNP) | VAF 25/207 reads (12%) | catalogued as COSV100974996; called by muse, mutect2, varscan2
- MARS1 | c.456A>G p.L152= | Silent (SNP) | VAF 54/588 reads (9%) | called by muse, mutect2
- MUC16 | c.32751C>A p.A10917= | Silent (SNP) | VAF 11/175 reads (6%) | catalogued as COSV67474475; called by muse, mutect2
- MYO19 | c.102G>C p.L34= | Silent (SNP) | VAF 48/264 reads (18%) | called by muse, mutect2, varscan2
- NEURL1 | c.912C>T p.H304= | Silent (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- NSUN2 | c.1203G>T p.L401= | Silent (SNP) | VAF 54/274 reads (20%) | catalogued as rs538147024; called by muse, mutect2, varscan2
- OR2L3 | c.825C>A p.V275= | Silent (SNP) | VAF 163/808 reads (20%) | called by muse, mutect2, varscan2
- OR5T3 | c.144C>T p.L48= | Silent (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- PORCN | c.477C>A p.L159= | Silent (SNP) | VAF 41/376 reads (11%) | called by muse, mutect2, varscan2
- RAB20 | c.462G>C p.A154= | Silent (SNP) | VAF 41/479 reads (9%) | called by muse, mutect2
- SLC22A24 | c.1563A>T p.L521= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as COSV70302973; called by muse, mutect2
- SLF1 | c.1606C>T p.L536= | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- VN1R5 | c.609G>T p.L203= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- AC116655.1 | n.700del | RNA (DEL) | VAF 45/360 reads (13%) | called by mutect2, pindel, varscan2
- ADA | c.679-30C>A | Intron (SNP) | VAF 74/978 reads (8%) | catalogued as COSV63068657; called by muse, mutect2
- DNAH2 | c.1904+169C>T | Intron (SNP) | VAF 67/230 reads (29%) | catalogued as rs754586484; called by muse, mutect2, varscan2
- DRAM1 | c.132-7723A>C | Intron (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- DYRK2 | c.198+1586G>T | Intron (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- FCRL2 | c.884-25C>G | Intron (SNP) | VAF 136/588 reads (23%) | called by muse, mutect2, varscan2
- GJD4 | c.-44C>A | 5'UTR (SNP) | VAF 45/581 reads (8%) | catalogued as COSV100397318; called by muse, mutect2
- LMF1 | c.1530-1293G>A | Intron (SNP) | VAF 13/111 reads (12%) | catalogued as rs766701169, COSV99236251; called by muse, mutect2, varscan2
- NUDT7 | c.348+724C>T | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3794G>T | Intron (SNP) | VAF 16/77 reads (21%) | catalogued as rs1255865556; called by muse, mutect2, varscan2
- VAMP7 | c.*21_*22delinsT | 3'UTR (DEL) | VAF 47/524 reads (9%) | called by pindel, varscan2*
- XIAP | c.*6637G>C | 3'UTR (SNP) | VAF 18/180 reads (10%) | catalogued as rs114568994, COSV63022620; called by muse, mutect2
